Gene-level copy-number profile of tumor specimen TCGA-D8-A140-01A from TCGA case TCGA-D8-A140, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.7 years (22,900 days).
Specimen TCGA-D8-A140-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.3551b6ac-c340-4640-9bbf-fe1181e1c773.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A140-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1610f81b-d3dd-4246-9c3d-07b6db7d218b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,663; copy number 2: 45,017; copy number 3: 5,315; copy number 4: 1,731; copy number 5: 750; copy number 6: 947; copy number 7: 199; copy number 8: 75; copy number 10: 1; copy number 11: 116.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A140-01A-11D-A111-01): tumor purity 0.7, ploidy 2.11, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,088 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,017,468–156,299,307, 503 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr1:156,463,727–161,964,070, 243 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:163,769,339–164,921,629, 13 genes, copy number 6: AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7.
- chr1:202,193,901–207,879,115, 185 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:211,829,636–218,918,714, 92 genes, copy number 5 (broad region; genes not listed).
- chr11:35,138,882–35,818,007, 12 genes, copy number 5 (within-gene range 3–5): CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44.
- chr12:63,142,759–63,668,939, 5 genes, copy number 5 (within-gene range 2–5): AVPR1A, AC135584.1, HNRNPA1P69, AC026116.1, DPY19L2.
- chr12:65,278,643–65,491,430, 1 gene, copy number 5 (within-gene range 2–5): MSRB3.
- chr12:65,418,731–68,576,136, 61 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr12:69,901,918–70,243,379, 1 gene, copy number 6 (within-gene range 3–6): PRANCR.
- chr12:70,180,338–76,620,043, 95 genes, copy number 5–6 (broad region; genes not listed).
- chr12:78,052,181–83,172,740, 59 genes, copy number 6: AC073571.1, PRXL2AP1, LINC02424, AC128707.1, AC130415.1, AC079362.1, AC068993.1, AC068993.2, SYT1, AC090709.1, AC027288.3, MIR1252, AC027288.2, AC027288.1, NOP56P3, PAWR, AC073569.2, PPP1R12A, AC073569.3, AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P, OTOGL, AC078817.1, RN7SKP261, PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618, ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1, AC091515.1, LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, AC091214.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1.
- chr12:85,781,892–85,782,444, 1 gene, copy number 10: AC137768.1.
- chr17:38,297,023–41,055,230, 142 genes, copy number 5 (broad region; genes not listed).
- chr17:49,505,657–49,574,064, 1 gene, copy number 5 (within-gene range 2–5): AC006487.1.
- chr17:49,544,788–56,511,659, 127 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr17:57,685,529–68,601,367, 357 genes, copy number 7–11 (broad region; genes not listed).
- chr17:73,334,384–74,531,475, 25 genes, copy number 6 (within-gene range 2–6): SDK2, AC124804.1, AC032019.1, AC032019.2, AC125421.1, LINC00469, LINC02092, AC125421.2, AC137735.1, AC137735.3, AC137735.2, LINC02074, RPL38, MGC16275, TTYH2, AC100786.1, DNAI2, AC103809.1, KIF19, BTBD17, GPR142, RNA5SP448, GPRC5C, CD300A, CD300LB.
- chr17:75,032,575–75,065,889, 2 genes, copy number 5 (within-gene range 3–5): KCTD2, ATP5PD.
- chr17:75,060,491–75,667,189, 35 genes, copy number 5 (within-gene range 1–5): AC111186.1, TRIM80P, SLC16A5, Y_RNA, ARMC7, NT5C, AC022211.4, JPT1, AC022211.3, AC022211.1, Y_RNA, SUMO2, NUP85, GGA3, MRPS7, MIF4GD, AC022211.2, SLC25A19, GRB2, AC011933.1, AC011933.4, AC011933.2, AC011933.3, MIR3678, RNU6-938P, Y_RNA, TMEM94, MIR6785, CASKIN2, TSEN54, LLGL2, MYO15B, RECQL5, SMIM5, SMIM6.
- chr19:14,477,760–16,660,115, 123 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:39,757,202–40,126,357, 5 genes, copy number 6 (within-gene range 3–6): AL118523.1, HSPE1P1, LINC01370, AL133419.1, AL009050.1.

Autosomal genes at a single copy (total copy number 1): 5,663. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
